Somatic mutation profile of cancer-model specimen HCM-CSHL-0821-C19-85M (3D Organoid, passage 4; aliquot HCM-CSHL-0821-C19-85M-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0821-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,269 days).
Specimen HCM-CSHL-0821-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f579f6d-0b7b-4890-8800-9d184e97b674.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0821-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0821-C19-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710269e5-8d5c-4868-b3c1-7ef95942adfa

The open-access MAF lists 141 somatic variants for this specimen: 86 protein-altering or splice-affecting, 53 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 53, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1, Translation Start Site 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAF | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 377/964 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1057519786, COSV51691446, COSV51693647, COSV51695114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 228/228 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AATK | c.1787G>A p.R596H (on ENST00000326724 / NM_001080395.3; = p.R493H on NM_004920.2) | Missense Mutation (SNP) | VAF 212/676 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs753171470, COSV100353433; called by muse, mutect2, varscan2
- ABCB5 | c.1881del p.A628Lfs*8 (on ENST00000404938 / NM_001163941.2; = p.A183Lfs*8 on NM_178559.6) | Frame Shift Del (DEL) | VAF 113/274 reads (41%) | catalogued as rs1452328679; called by mutect2, pindel, varscan2
- ACTN2 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 266/372 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370569935; ClinVar: uncertain significance; called by muse, varscan2
- ARHGEF10 | c.3358G>A p.V1120I (on ENST00000398564; = p.V1095I on NM_014629.4) | Missense Mutation (SNP) | VAF 257/582 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); catalogued as rs776440131, COSV100033483; called by muse, mutect2, varscan2
- ARL11 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 44/1142 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as rs994780789, COSV56290713; called by muse, mutect2
- ASTN1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 70/776 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1345907735, COSV56075116; called by muse, mutect2
- BFSP2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 200/668 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs780733122, COSV56590024; called by muse, mutect2
- CCDC87 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 177/513 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs767088192; called by muse, mutect2, varscan2
- CCDC88C | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs769712056, COSV66238226; called by muse, mutect2, varscan2
- CEACAM4 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 280/527 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs782116692, COSV55731143; called by muse, mutect2, varscan2
- COG7 | c.1401C>G p.N467K | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as rs757733010, COSV100207432; called by muse, mutect2
- COL17A1 | c.3866G>A p.S1289N | Missense Mutation (SNP) | VAF 157/457 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs541222706; called by muse, mutect2, varscan2
- CRB1 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 111/400 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749366098, COSV66333419; called by muse, mutect2, varscan2
- CSMD3 | c.8721G>C p.M2907I (on ENST00000297405 / NM_001363185.1; = p.M2738I on NM_052900.3) | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV52168744; called by muse, mutect2, varscan2
- DGAT2L6 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 163/847 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs149063119; called by muse, mutect2, varscan2
- DLG3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 557/931 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as COSV99529850; called by muse, mutect2, varscan2
- DOCK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201322810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1E1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 192/383 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776293830; called by muse, mutect2, varscan2
- ELAPOR2 | c.1978G>T p.G660W (on ENST00000450689 / NM_001142749.3; = p.G493W on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788434; called by muse, mutect2, varscan2
- FAM47A | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 248/626 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as rs780521265, COSV60495193, COSV60498365, COSV60499348; called by muse, varscan2
- FCRL3 | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV63841339; called by muse, mutect2
- FGF9 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 39/872 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs371548027, COSV66646020; called by muse, mutect2
- H2BC13 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 140/265 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.885); catalogued as rs368046141; called by muse, mutect2, varscan2
- KCNA5 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 276/424 reads (65%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs201328038; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- KRT82 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 261/417 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs774205887, COSV57785705; called by muse, mutect2, varscan2
- LCT | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 177/275 reads (64%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs762388454, COSV51543557; called by muse, mutect2, varscan2
- LRRTM3 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 211/324 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63670197; called by muse, mutect2, varscan2
- MAP3K21 | c.3061A>G p.K1021E | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs1336690329; called by muse, mutect2, varscan2
- MCF2L | c.1475C>T p.A492V (on ENST00000375608; = p.A460V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/978 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs936405302; called by muse, mutect2, varscan2
- MOXD1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 183/374 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs377603332; called by muse, mutect2, varscan2
- MYO15A | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 401/404 reads (99%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99233655; called by muse, mutect2, varscan2
- OR51A7 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV63788646; called by muse, mutect2, varscan2
- OR8K3 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs377327048; called by muse, mutect2, varscan2
- PCDHGA6 | c.748A>G p.S250G | Missense Mutation (SNP) | VAF 77/534 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV53922652; called by muse, mutect2, varscan2
- PCDHGB5 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 345/688 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.382); catalogued as rs1222355355, COSV99550566; called by muse, mutect2, varscan2
- PIEZO2 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1298773035; called by muse, mutect2, varscan2
- PKHD1 | c.2636C>T p.T879M | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as rs141638079; called by muse, mutect2
- PODN | c.1102G>A p.A368T (on ENST00000395871; = p.A320T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/262 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.103); catalogued as rs757792597, COSV100439270; called by muse, mutect2, varscan2
- POTEE | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 106/606 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs747324485, COSV58238683; called by muse, varscan2
- SIK3 | c.2012C>A p.A671D (on ENST00000445177 / NM_001366686.2; = p.A629D on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52613507; called by muse, mutect2, varscan2
- SLC6A5 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 187/604 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs750746291; called by muse, mutect2, varscan2
- SLC7A3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 359/829 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.171); catalogued as rs776425784, COSV53227212; called by muse, mutect2, varscan2
- SNTB1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 82/431 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as rs752413892, COSV67324433; called by muse, mutect2, varscan2
- SPRED3 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 315/776 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs1268272414; called by muse, mutect2, varscan2
- SSBP3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs374519094; called by muse, mutect2, varscan2
- STRN | c.659+1G>A p.X220_splice | Splice Site (SNP) | VAF 36/158 reads (23%) | catalogued as rs1337335720, COSV55746809; called by muse, mutect2, varscan2
- TMEM177 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746087035, COSV55609603; called by muse, mutect2, varscan2
- UBE4B | c.2185G>A p.A729T (on ENST00000343090 / NM_001105562.3; = p.A600T on NM_006048.5) | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.824); catalogued as COSV99477826; called by muse, mutect2, varscan2
- UROC1 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 125/376 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758929808, COSV52037733; called by muse, mutect2, varscan2
- USP32 | c.4652C>T p.P1551L | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs775749225, COSV56270547; called by muse, mutect2, varscan2
- VSTM1 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 113/554 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770554061, COSV58074308; called by muse, mutect2, varscan2
- ZNF521 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 56/528 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs777891991; called by muse, mutect2, varscan2
- ADAMTS6 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGPAT4 | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 218/463 reads (47%) | called by muse, mutect2, varscan2
- ANKRD24 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 72/484 reads (15%) | called by muse, mutect2, varscan2
- APOC2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 162/306 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- DCAF5 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK2 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 146/269 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DLG3 | c.1271G>T p.G424V (on ENST00000374360 / NM_021120.4; = p.G87V on NM_020730.3) | Missense Mutation (SNP) | VAF 336/581 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EYS | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FGFRL1 | c.821_825del p.V274Afs*35 | Frame Shift Del (DEL) | VAF 335/801 reads (42%) | called by mutect2, pindel, varscan2
- GSTT2B | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by mutect2, varscan2
- IQCG | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 112/355 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ITPRID2 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 156/432 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP3-2 | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 138/557 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.741); called by muse, mutect2
- KRTAP3-3 | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 70/838 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.518); called by muse, mutect2
- MAP3K6 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 147/314 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OR10K1 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR11H2 | c.153dup p.V52Cfs*5 (on ENST00000556246; = p.V63Cfs*5 on NM_001197287.1) | Frame Shift Ins (INS) | VAF 8/83 reads (10%) | called by pindel, varscan2
- PLA1A | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PLA2R1 | c.3438A>C p.K1146N | Missense Mutation (SNP) | VAF 112/339 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIL4 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 152/348 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- RPS26 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RWDD2B | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAP18 | c.244A>C p.K82Q (on ENST00000607003; = p.K101Q on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/639 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2
- SEMA4G | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3GLB1 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SHC3 | c.1109_1113dup p.F372Pfs*16 | Frame Shift Ins (INS) | VAF 57/238 reads (24%) | called by mutect2, varscan2
- SLC8A2 | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 202/377 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SNX12 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 78/806 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- STMN4 | c.184C>T p.Q62* (on ENST00000265770 / NM_001283054.2; = p.Q89* on NM_030795.4) | Nonsense Mutation (SNP) | VAF 141/213 reads (66%) | called by muse, mutect2, varscan2
- UBASH3B | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 193/295 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZFC3H1 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF865 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 164/577 reads (28%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- AL645922.1 | c.2118G>A p.T706= | Silent (SNP) | VAF 354/747 reads (47%) | catalogued as rs757199192; called by muse, mutect2, varscan2
- AR | c.1200G>A p.A400= | Silent (SNP) | VAF 86/1186 reads (7%) | called by muse, mutect2
- ATG16L1 | c.1536A>G p.L512= (on ENST00000392017 / NM_030803.7; = p.L493= on NM_017974.4) | Silent (SNP) | VAF 205/334 reads (61%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.1671C>T p.Y557= | Silent (SNP) | VAF 222/324 reads (69%) | catalogued as rs370651951; called by muse, mutect2, varscan2
- CASR | c.2313G>A p.L771= (on ENST00000490131; = p.L848= on NM_000388.4) | Silent (SNP) | VAF 136/392 reads (35%) | called by muse, mutect2, varscan2
- CIB3 | c.150C>T p.P50= | Silent (SNP) | VAF 172/354 reads (49%) | catalogued as rs371720260; called by muse, mutect2, varscan2
- CLPTM1 | c.387C>T p.H129= | Silent (SNP) | VAF 53/474 reads (11%) | catalogued as rs756631414; called by muse, mutect2, varscan2
- CNOT1 | c.5241G>A p.A1747= | Silent (SNP) | VAF 37/234 reads (16%) | catalogued as rs781409507; called by muse, mutect2, varscan2
- COL18A1 | c.3393G>A p.S1131= (on ENST00000359759 / NM_130444.3; = p.S896= on NM_030582.4) | Silent (SNP) | VAF 207/326 reads (63%) | catalogued as rs374522196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF1 | c.1698C>T p.D566= | Silent (SNP) | VAF 137/440 reads (31%) | catalogued as rs782612493, COSV62941774; called by muse, mutect2, varscan2
- CPZ | c.651C>T p.F217= (on ENST00000360986 / NM_001014447.3; = p.F206= on NM_003652.3) | Silent (SNP) | VAF 64/321 reads (20%) | catalogued as rs560825263; called by muse, mutect2, varscan2
- CRAMP1 | c.186C>T p.P62= | Silent (SNP) | VAF 276/495 reads (56%) | called by muse, mutect2, varscan2
- DGKG | c.1152C>T p.D384= | Silent (SNP) | VAF 171/265 reads (65%) | catalogued as rs770406720, COSV53974153; called by muse, mutect2, varscan2
- DMD | c.9510C>T p.N3170= | Silent (SNP) | VAF 141/817 reads (17%) | catalogued as rs751900100; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHA10 | c.711C>T p.A237= | Silent (SNP) | VAF 192/418 reads (46%) | called by muse, mutect2, varscan2
- EPHA6 | c.123G>A p.S41= | Silent (SNP) | VAF 370/567 reads (65%) | catalogued as rs761268918; called by muse, mutect2, varscan2
- EXOSC10 | c.54C>T p.T18= | Silent (SNP) | VAF 130/275 reads (47%) | called by muse, mutect2, varscan2
- FLNB | c.3162C>T p.L1054= | Silent (SNP) | VAF 56/345 reads (16%) | catalogued as rs762025870, COSV55875044; called by muse, mutect2, varscan2
- FPGT | c.1590G>A p.K530= | Silent (SNP) | VAF 99/216 reads (46%) | catalogued as COSV100907628; called by muse, mutect2, varscan2
- GPR6 | c.678C>T p.H226= | Silent (SNP) | VAF 88/880 reads (10%) | catalogued as rs746166061; called by muse, mutect2
- GRM7 | c.1746C>T p.I582= | Silent (SNP) | VAF 58/392 reads (15%) | catalogued as rs552009676; called by muse, mutect2, varscan2
- H2AC14 | c.159G>A p.A53= | Silent (SNP) | VAF 25/318 reads (8%) | catalogued as rs779362597; called by muse, mutect2, varscan2
- HEATR1 | c.972A>G p.L324= | Silent (SNP) | VAF 77/318 reads (24%) | called by muse, mutect2, varscan2
- IQGAP3 | c.3534C>T p.R1178= | Silent (SNP) | VAF 35/342 reads (10%) | catalogued as rs1281749606; called by muse, mutect2, varscan2
- KIFAP3 | c.885C>T p.T295= | Silent (SNP) | VAF 296/444 reads (67%) | catalogued as rs770475559; called by muse, mutect2, varscan2
- MAST4 | c.7626C>T p.G2542= (on ENST00000403625 / NM_001164664.2; = p.G2353= on NM_015183.3) | Silent (SNP) | VAF 311/311 reads (100%) | catalogued as rs764979550; called by muse, mutect2, varscan2
- MXRA5 | c.6183G>A p.P2061= | Silent (SNP) | VAF 380/1056 reads (36%) | catalogued as rs746083731; called by muse, mutect2, varscan2
- NHSL1 | c.1782G>A p.T594= | Silent (SNP) | VAF 188/416 reads (45%) | catalogued as rs375605967; called by muse, mutect2, varscan2
- NIBAN3 | c.1179G>A p.A393= | Silent (SNP) | VAF 329/631 reads (52%) | catalogued as rs995297747, COSV56307006; called by muse, mutect2, varscan2
- PCDHGB5 | c.1320C>T p.D440= | Silent (SNP) | VAF 258/572 reads (45%) | called by muse, mutect2, varscan2
- PKD2L2 | c.144G>A p.G48= | Silent (SNP) | VAF 114/247 reads (46%) | catalogued as rs1454485169; called by muse, mutect2, varscan2
- PPARGC1B | c.2106C>T p.G702= | Silent (SNP) | VAF 88/643 reads (14%) | catalogued as rs1403317878; called by muse, mutect2, varscan2
- PRPF4B | c.1143C>T p.S381= | Silent (SNP) | VAF 81/336 reads (24%) | called by muse, mutect2, varscan2
- PTH1R | c.1587C>T p.N529= | Silent (SNP) | VAF 237/681 reads (35%) | catalogued as rs199557895; called by muse, mutect2, varscan2
- RHBDF2 | c.1107C>T p.Y369= | Silent (SNP) | VAF 290/417 reads (70%) | catalogued as rs769363909, COSV57420767; called by muse, mutect2, varscan2
- RPS6KA4 | c.300G>A p.T100= | Silent (SNP) | VAF 140/506 reads (28%) | called by muse, mutect2, varscan2
- RYR3 | c.8727C>T p.L2909= (on ENST00000389232; = p.L2910= on NM_001036.6) | Silent (SNP) | VAF 211/332 reads (64%) | catalogued as rs370300379; called by muse, mutect2, varscan2
- SCYL2 | c.2355C>T p.N785= | Silent (SNP) | VAF 257/371 reads (69%) | catalogued as COSV62569476; called by muse, mutect2, varscan2
- SETD1B | c.2076C>A p.P692= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as rs1368043466, COSV57355054; called by mutect2, varscan2
- SLC35G5 | c.864C>T p.S288= | Silent (SNP) | VAF 224/437 reads (51%) | catalogued as rs762601745, COSV55312509; called by muse, mutect2, varscan2
- SLC41A1 | c.210G>A p.G70= | Silent (SNP) | VAF 170/747 reads (23%) | catalogued as rs889750808; called by muse, mutect2, varscan2
- SMARCA4 | c.147G>A p.P49= | Silent (SNP) | VAF 95/847 reads (11%) | catalogued as rs758438795; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- ST14 | c.615A>G p.T205= | Silent (SNP) | VAF 179/274 reads (65%) | called by muse, mutect2, varscan2
- STXBP5L | c.90T>G p.G30= | Silent (SNP) | VAF 110/328 reads (34%) | called by muse, mutect2, varscan2
- SYNDIG1L | c.663C>T p.Y221= | Silent (SNP) | VAF 150/285 reads (53%) | catalogued as rs763935499; called by muse, mutect2, varscan2
- TAAR8 | c.408C>T p.P136= | Silent (SNP) | VAF 114/495 reads (23%) | catalogued as COSV51587004; called by muse, mutect2, varscan2
- TBC1D25 | c.1974C>T p.R658= | Silent (SNP) | VAF 534/925 reads (58%) | catalogued as rs781801055; called by muse, mutect2, varscan2
- TBX18 | c.408G>A p.P136= | Silent (SNP) | VAF 44/862 reads (5%) | catalogued as rs924714791, COSV63737870; called by muse, mutect2
- TPO | c.1293C>T p.D431= | Silent (SNP) | VAF 206/593 reads (35%) | catalogued as rs753971477; called by muse, mutect2, varscan2
- TRPS1 | c.3471A>T p.G1157= (on ENST00000220888 / NM_001330599.2; = p.G1170= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 272/413 reads (66%) | called by muse, mutect2, varscan2
- UNC13A | c.4776T>C p.N1592= | Silent (SNP) | VAF 162/451 reads (36%) | called by muse, mutect2, varscan2
- VGLL4 | c.348C>T p.H116= | Silent (SNP) | VAF 331/531 reads (62%) | catalogued as rs145939148; called by muse, mutect2, varscan2
- WSB2 | c.465C>T p.V155= | Silent (SNP) | VAF 190/318 reads (60%) | catalogued as rs763533797, COSV59574165; called by muse, mutect2, varscan2
- EFEMP2 | c.*265G>A | 3'UTR (SNP) | VAF 280/424 reads (66%) | catalogued as rs772435021; called by muse, varscan2
- ZNF582 | chr19:56394311 C>T | 5'Flank (SNP) | VAF 40/374 reads (11%) | called by muse, mutect2
